TCGA case TCGA-86-7701 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3f6bc1c-19ab-4eeb-a9ac-3d2fac850bde

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 66 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 66.3 years (24,209 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide; Days to treatment start: 27 days; Days to treatment end: 207 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 454 days (1.2 years); Days to treatment end: 601 days (1.6 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Tyrosine Kinase Inhibitor; Days to treatment start: 454 days (1.2 years); Days to treatment end: 601 days (1.6 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Zoledronic Acid; Days to treatment start: 454 days (1.2 years); Days to treatment end: 601 days (1.6 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Zoledronic Acid; Days to treatment start: 706 days (1.9 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 917 days (2.5 years); Days to treatment end: 929 days (2.5 years); Treatment dose: 29 Gy; Treatment outcome: Progressive Disease; Number of fractions: 13; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Gemcitabine; Days to treatment start: 936 days (2.6 years); Treatment outcome: Treatment Ongoing.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 67.4 years (24,633 days); Days to diagnosis: 424 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.
3. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 68.7 years (25,109 days); Days to diagnosis: 900 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (7 entries)
- Days to follow up: 11 days; Disease response: Tumor Free.
- Day 424 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 424 days (1.2 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 474 days (1.3 years); Disease response: With Tumor.
- Day 900 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 900 days (2.5 years).
- Days to follow up: 947 days (2.6 years); Disease response: With Tumor.
- Karnofsky performance status: 80; ECOG performance status: 2; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-86-7701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 1.7; Shortest dimension: 0.2.
  Slide TCGA-86-7701-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 2; Percent stromal cells: 23; Percent lymphocyte infiltration: 8.
  Slide TCGA-86-7701-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 15; Percent necrosis: 10; Percent stromal cells: 15; Percent lymphocyte infiltration: 10.
- Sample TCGA-86-7701-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-86-7701-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Peripheral Lung; Pulmonary function test indicator: No.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 1, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 947 days; disease-specific survival: no event (censored), 947 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 424 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-86-7701-01A-11D-2166-01): tumor purity 0.42, ploidy 2.97, whole-genome doublings 1.
